CCDI case PBBWDF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d899e8a8-aefc-4bb3-9ff9-eb9150169692

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.2 years (1,518 days).

Biospecimens (3 samples)
- Sample 0DIPKT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPLD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DIPLT: Tissue type: Tumor; Specimen type: Solid Tissue.
